Somatic mutation profile of tumor specimen 0DNMB4 from CCDI case PBCBIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,609 days).
Specimen 0DNMB4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 787bf964-d322-4df4-8a09-3230813e5b93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNM9Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4089752c-786e-4d08-9368-e7dfefc7102b

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 5'UTR 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 40/706 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs566240276, COSV70028171; called by muse, mutect2
- CHRNB4 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 54/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55714792; called by muse, mutect2, varscan2
- GDF5 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65501084; called by muse, mutect2, varscan2
- GPX2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 174/412 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs761968560; called by muse, mutect2, varscan2
- HEATR9 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 96/493 reads (19%) | catalogued as rs377561711; called by muse, mutect2, varscan2
- HSPA12A | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as rs1423363716, COSV65024226; called by muse, mutect2, varscan2
- MGA | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54950159; called by muse, mutect2
- SH2B2 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs1241557575; called by muse, mutect2, varscan2
- BCAR1 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CTDNEP1 | c.118dup p.T40Nfs*5 | Frame Shift Ins (INS) | VAF 236/376 reads (63%) | called by mutect2, pindel, varscan2
- KIF24 | c.3440_3442del p.E1147del | In Frame Del (DEL) | VAF 22/251 reads (9%) | called by mutect2, pindel
- MARCHF6 | c.2217T>G p.F739L | Missense Mutation (SNP) | VAF 32/603 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- MKI67 | c.2762A>G p.E921G | Missense Mutation (SNP) | VAF 78/522 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRMT9 | c.1119T>G p.I373M | Missense Mutation (SNP) | VAF 220/477 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- PROKR1 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 153/291 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DUSP8 | c.1065C>A p.G355= | Silent (SNP) | VAF 80/99 reads (81%) | catalogued as rs757072093, COSV59031472; called by muse, mutect2, varscan2
- PCDHB11 | c.1272C>T p.T424= | Silent (SNP) | VAF 117/351 reads (33%) | catalogued as COSV100697033; called by muse, mutect2, varscan2
- POMC | c.639C>T p.A213= | Silent (SNP) | VAF 123/256 reads (48%) | called by muse, mutect2, varscan2
- TCF3 | c.1386C>T p.H462= | Silent (SNP) | VAF 153/332 reads (46%) | catalogued as rs746116389, COSV53646700; called by muse, mutect2, varscan2
- LY6K | c.-1G>A | 5'UTR (SNP) | VAF 121/425 reads (28%) | catalogued as rs782631942; called by muse, mutect2, varscan2
- NAA60 | c.-7+9469G>C | Intron (SNP) | VAF 12/100 reads (12%) | catalogued as rs957011245; called by muse, mutect2, varscan2
